Gene-level copy-number profile of tumor specimen ALCH-B359-TTP1-A from ALCHEMIST case ALCH-B359, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.8 years (27,694 days).
Specimen ALCH-B359-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cdb91ed1-12f7-4c97-8e13-224cad9fe61d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B359-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/d235a952-1409-4ebf-9c8d-5c302429d150

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 2,511; copy number 2: 55,354; copy number 3: 461; copy number 4: 22; copy number 5: 5; copy number 6: 4; copy number 7: 5; copy number 8: 4; copy number 9: 1; copy number 17: 2; copy number 36: 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,773,738–12,823,159, 3 genes: PRAMEF12, PRAMEF1, LINC01784.
- chr1:12,847,377–12,928,253, 7 genes (within-gene range 0–1): HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P.
- chr1:20,732,880–20,733,952, 1 gene: AL663074.1.
- chr2:91,617,160–91,659,972, 1 gene (within-gene range 0–2): LSP1P4.
- chr4:188,139,441–188,147,743, 2 genes: TRIML1, AC138781.1.
- chr7:5,475,804–5,479,811, 1 gene (within-gene range 0–2): AC092171.2.
- chr7:74,289,407–74,405,935, 1 gene: CLIP2.
- chr7:99,374,249–99,394,816, 1 gene (within-gene range 0–1): ARPC1B.
- chr7:99,442,890–99,443,496, 1 gene (within-gene range 0–1): AC073063.1.
- chr9:138,177,426–138,179,774, 1 gene: AL591424.2.
- chr16:89,919,165–89,938,761, 3 genes (within-gene range 0–5): AC092143.1, AC092143.2, TUBB3.
- chr17:8,079,482–8,081,565, 1 gene (within-gene range 0–1): AC129492.1.
- chr17:22,519,617–22,520,709, 1 gene: MTCYBP13.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,032,130, 2 genes, copy number 5 (within-gene range 0–5): PRAMEF6, PRAMEF28P.
- chr2:242,087,351–242,088,457, 1 gene, copy number 9: AC093642.2.
- chr6:32,517,353–32,530,287, 1 gene, copy number 5: HLA-DRB5.
- chr6:32,578,769–32,589,848, 1 gene, copy number 5: HLA-DRB1.
- chr9:136,744,017–136,766,255, 4 genes, copy number 6–17 (within-gene range 4–17): LCN6, MIR6722, LCN8, LCN15.
- chr9:136,969,243–136,985,435, 3 genes, copy number 5–8 (within-gene range 4–8): LINC02692, PTGDS, AL807752.7.
- chr9:137,007,234–137,028,922, 1 gene, copy number 7 (within-gene range 2–7): ABCA2.
- chr9:137,039,463–137,054,061, 3 genes, copy number 6–8 (within-gene range 2–8): NPDC1, ENTPD2, AL807752.4.
- chr9:138,217,068–138,253,217, 1 gene, copy number 8: FAM157B.
- chr17:18,393,480–18,400,961, 1 gene, copy number 36: TBC1D3P4.
- chr17:18,450,244–18,475,920, 4 genes, copy number 7: KRT16P4, AL353997.1, AL353997.4, TNPO1P2.

Autosomal genes at a single copy (total copy number 1): 2,506. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
